CCDI case PBCDGF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6ceb589c-acca-4eda-85de-3723c1685c49

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,231 days).

Biospecimens (3 samples)
- Sample 0DP4P6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4PK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP4Q6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
